FM case AD198 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/0d3b9cba-5a44-4398-9c30-80a00515406b

Female, 42.4 years: diagnosis not reported by GDC. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Tumor.
